Surgical pathology report (de-identified scan), TCGA case TCGA-60-2714, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2714-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 10R LYMPH NODE
B. RIGHT LUNG WITH PORTION AZYGOUS VEIN
C. 10R LYMPH NODE
D. LEVEL 8 LYMPH NODE
E. LEVEL 7 LYMPH NODE
F. LEVEL 9 LYMPH NODE

CLINICAL HISTORY:

PRE-OPERATIVE DIAGNOSIS:

Right lower lobe mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSB: Right lung resection: Bronchial margin is free of tumor

GROSS DESCRIPTION:

A. 10R LYMPH NODE

Received in formalin is a single portion of tan-red soft tissue measuring 1.2x0.7x0.4cm. Specimen is bisected longitudinally and submitted in toto for microscopic examination in cassette A1.

B. RIGHT LUNG WITH PORTION AZYGOUS VEIN

Received fresh labeled with patients name and "right lung with portion of azygous vein" is a 625gm, 20x15x12cm lung lobectomy specimen. There is puckering of the pleural surface that is inked black. The specimen sectioned to reveal a 7.0x5.0x4.0cm tan-white to gray-black mass located 1.5 cm from the bronchial margin and grossly extending to the pleural surface. The mass encircles but grossly does not appear to invade the vascular or bronchial passages. The uninvolved parenchyma is red-brown in color and otherwise unremarkable. Located near the resection margin is a venous segment measuring 2.0cm in length by 0.7cm in diameter. It is

[page 2 of 3]
[REDACTED]

closed by a staple line at both ends. Multiple peribronchial lymph nodes are identified, the largest measuring 1.1 cm in greatest dimension. The bronchial margin is shaved and submitted for frozen section. Tissue is obtained for procurement. Sections for microscopic examination:

B2-B8: representatives of the mass

B9: representative of unremarkable parenchyma and representative section of vein

B10: 1 presumptive lymph node, bisected

B11: 6 presumptive lymph nodes

B12: 1 presumptive lymph node, bisected

B13: 5 presumptive lymph nodes

B14-B21: 1 presumptive lymph node in each cassette

C. 10R LYMPH NODE

Received in formalin are 2 portions of tan-purple soft tissue. The smaller measures 0.7x0.4x0.3cm. The larger 0.8x0.7x0.5cm. The smaller fragment is inked black and submitted in toto as received. The larger fragment is bisected longitudinally and submitted in toto. All tissue has been submitted, 3 pieces 1 cassette labeled C1.

D. LEVEL 8 LYMPH NODE

Received in formalin are 7 fragments of yellow and red soft tissue ranging in size from 0.7x0.4x0.2cm to 1.5x1.5x1.0cm. Cassette summary:

D1: 3 presumptive lymph nodes

D2-D5: 1 presumptive lymph node in each cassette

E. LEVEL 7 LYMPH NODE

Received in formalin are 2 fragments of tan-gray to red soft tissue. The smaller measures 1.3x1.5x1.0cm. The larger 2.0x2.0x1.0cm. One fragment is trisected and submitted in toto in E1. The second fragment is serially sectioned and submitted in E2.

F. LEVEL 9 LYMPH NODE

Received in formalin is a single fragment of tan-gray soft tissue measuring 1.2x0.6x0.5cm. The specimen is bisected and submitted in toto for microscopic examination in cassette F.

[REDACTED]

DIAGNOSIS:

A. LYMPH NODE, 10R, EXCISION:

-ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

B. LUNG, RIGHT, PNEUMONECTOMY:

-POORLY DIFFERENTIATED, NON-SMALL CELL CARCINOMA, MOST PROBABLY SQUAMOUS CELL CARCINOMA MEASURING 7 x 4 CM.

-PERIBRONCHIAL LYMPH NODES, POSITIVE FOR CARCINOMA (2/17).

C. LYMPH NODE, 10R, EXCISION:

-ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

D. LYMPH NODES, LEVEL 8, EXCISION:

-SEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/7).

E. LYMPH NODES, LEVEL 7, EXCISION:

-TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

F. LYMPH NODE, LEVEL 9, EXCISION:

-ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

[REDACTED]

[page 3 of 3]
LUNG NEOPLASM TEMPLATE

Surgical procedure: pneumonectomy
Tumor location: peripheral, right upper lobe, right lower lobe
Tumor size: 7 x 4 cm
Tumor type: non-small cell carcinoma, squamous cell carcinoma
Histologic grade: poorly differentiated (G3)
Angiolymphatic invasion: present
Bronchial margin: negative
Visceral pleural involvement: absent
Satellite tumor(s): no
Lymph node involvement: N1:positive (2/19)
N2:Negative (0/10)
Non-neoplastic lung:
Pathologic stage: pT2 N1 Mx

Source: NCI Genomic Data Commons file 86427e67-e13d-4892-878d-6d945d655dcc (TCGA-60-2714.8C5C0056-9AE8-42E2-8A8F-CDF2F7BBBAA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).